Gene-level copy-number profile of tumor specimen HCM-CSHL-0187-C25-01A from HCMI case HCM-CSHL-0187-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 67.2 years (24,541 days).
Specimen HCM-CSHL-0187-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8fa60026-a9e0-4788-a3f4-3f20a501d429.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0187-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/0f52c1cc-e400-45c7-9c17-81b102516945

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 179; copy number 1: 2; copy number 2: 15,662; copy number 3: 434; copy number 4: 36,176; copy number 5: 1,168; copy number 6: 3,705; copy number 7: 103; copy number 8: 901; copy number 9: 61; copy number 10: 443; copy number 11: 80.

Homozygous deletions (total copy number 0; autosomes only): 179 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:29,887,294–29,929,232, 7 genes: AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K.
- chr8:12,104,389–12,177,550, 7 genes (within-gene range 0–2): ZNF705D, FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P.
- chr9:12,958,503–13,836,571, 8 genes: AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235.
- chr9:19,409,009–32,526,208, 151 genes (broad region; genes not listed).
- chr15:34,489,002–34,588,503, 6 genes: HNRNPLP2, FSCN1P1, DNM1P5, GOLGA8B, MIR1233-2, AC027139.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 584 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:39,451,045–39,522,852, 1 gene, copy number 9: ADAM3A.
- chr8:102,252,273–102,412,759, 1 gene, copy number 9 (within-gene range 8–9): UBR5.
- chr8:102,417,979–105,804,539, 59 genes, copy number 9 (within-gene range 8–9): AP002981.1, RNU6ATAC8P, HSPE1P14, RPS12P15, AP002852.1, RNU6-1224P, ODF1, POU5F1P2, KLF10, ADI1P2, GASAL1, AZIN1, AP003696.1, MAILR, AP003354.1, RPL5P24, Y_RNA, NPM1P52, AP003550.1, ATP6V1C1, MTND1P5, MTCO1P4, MTCO2P4, LINC01181, BAALC-AS2, BAALC, BAALC-AS1, MIR3151, AC025370.1, FZD6, AC025370.2, CTHRC1, AC012213.3, RNU6-1011P, SLC25A32, AC012213.5, DCAF13, AC012213.2, AC012213.4, AC012213.1, RIMS2, PTMAP15, AC007751.1, AC090686.1, DPYS, DCSTAMP, AP003471.1, AP002847.1, MIR548A3, LRP12, NDUFA5P2, ZFPM2, AC012564.1, AC090142.2, AC090142.3, AC090142.1, AC021546.1, TMCC1P1, AC041039.1.
- chr8:106,215,763–140,638,283, 368 genes, copy number 10–11 (broad region; genes not listed).
- chr17:34,169,372–34,859,046, 15 genes, copy number 10 (within-gene range 8–10): LINC01989, AC005549.1, CCL2, CCL7, CCL11, CCL8, AC011193.2, CCL13, CCL1, AC011193.1, C17orf102, TMEM132E, AC005691.1, AC005552.1, AC022903.1.
- chr17:49,700,934–51,521,401, 86 genes, copy number 10 (broad region; genes not listed).
- chr17:75,441,159–75,765,236, 14 genes, copy number 10: TMEM94, MIR6785, CASKIN2, TSEN54, LLGL2, MYO15B, RECQL5, SMIM5, SMIM6, SAP30BP, AC087749.2, AC087749.1, ITGB4, GALK1.
- chr18:45,034–1,310,018, 40 genes, copy number 10 (within-gene range 6–10): AP001005.1, TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
